Surgical pathology report (de-identified scan), TCGA case TCGA-EU-5905, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-EU-5905-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

SPECIMEN

A. KIDNEY - 1. Right kidney to [REDACTED] [REDACTED]

CLINICAL INFORMATION

Renal mass, right

[REDACTED]

GROSS DESCRIPTION

The specimen is received in formalin labeled with the patient's name [REDACTED] and additionally labeled "right kidney to pathology [REDACTED]" and consists of a 232 gm kidney with perirenal adipose tissue. The kidney measures 8.5 x 5.5 x 5.5 cm. There is an attached segment of ureter measuring 5.5 cm in length with an average diameter of 0.4 cm. There is a 3 x 3 x 2.8 cm encapsulated, well-circumscribed orange-red cystic mass in the lower pole of the kidney. The mass is 1 cm away from the ureter and does not invade the renal vein. The mass extends to the renal capsule but does not invade through the renal capsule. The renal capsule is purple-tan, smooth and glistening with a slight bulge overlying the area of tumor. No adrenal gland is identified. No lymph nodes are identified. The cortical medullary junction is distinct and the cortex measures 0.6 cm. The uninvolved kidney is tan with unremarkable medullary pyramids. The following representative sections are submitted.

SLIDE KEY

A1 - ureter margin
A2 - vascular margin
A3 - tumor and ureter
A4 - tumor and capsule
A5 - tumor and capsule
A6 - tumor and adjacent parenchyma
A7 - uninvolved kidney

[REDACTED]

MICROSCOPIC DESCRIPTION

[REDACTED]

[page 2 of 2]
[REDACTED]

Sections from the ureteral and vascular margins are free of neoplasm. Sections from the tumor show a renal cell carcinoma, clear cell type, Fuhrman nuclear grade 3. The tumor extends up to the renal capsule.

Please refer to the cancer case summary for additional findings.

Surgical Pathology Cancer Case Summary, Kidney

SPECIMEN TYPE: Right radical nephrectomy, without adrenal.

TUMOR SITE: Lower pole.

TUMOR SIZE: 3 x 3 x 2.8 cm.

MACROSCOPIC EXTENT OF TUMOR: Limited to kidney.

HISTOLOGIC TYPE: Conventional (clear cell) renal cell carcinoma.

HISTOLOGIC GRADE: G3 (Fuhrman grade 3).

EXTENT OF INVASION: T1.

MARGINS: Uninvolved by tumor.

BLOOD/LYMPHATIC VESSEL INVASION: Not observed.

REGIONAL LYMPH NODES: NX: Cannot be assessed (none included with specimen).

DISTANT METASTASIS: MX: Cannot be assessed.

ADDITIONAL PATHOLOGIC FINDINGS: Examination of the adjacent benign kidney shows severe arteriosclerosis but very little nephrosclerosis. Less than 5% of the tubular parenchyma is atrophic, and less than 5% of the glomeruli are obsolescent. Nearly all of the arteries, however, show prominent subendothelial fibroplasia.

[REDACTED]

FINAL DIAGNOSIS

KIDNEY, RIGHT, NEPHRECTOMY

- Renal cell carcinoma, clear cell pattern, Fuhrman grade 3.
- Examined margins free of neoplasm.
- Maximal tumor diameter 3 cm.
- Please see microscopic note and cancer case summary.
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 37bb60ad-17bc-4b67-9c53-f206efd7a065 (TCGA-EU-5905.3E745E28-FE5E-40D0-8493-697D2592C359.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).